CCDI case PBCJBC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/44f7323a-a976-4580-ab75-96ac9c29a1ea

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.1 years (2,955 days).

Biospecimens (2 samples)
- Sample 0DTHM0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTHMC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
